Gene-level copy-number profile of tumor specimen TCGA-EA-A5ZF-01A from TCGA case TCGA-EA-A5ZF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 56.1 years (20,506 days).
Specimen TCGA-EA-A5ZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.8e1bbdc9-cd19-4dcc-ab9b-3fd4a7ad7272.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A5ZF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/74a211d3-bb40-49ee-9ee6-340ac0a07df6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,998; copy number 2: 24,421; copy number 3: 15,326; copy number 4: 13,060; copy number 5: 470; copy number 6: 3,397; copy number 7: 146.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EA-A5ZF-01A-11D-A28A-01): tumor purity 0.73, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,013 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr16:11,547,722–11,828,845, 8 genes, copy number 6 (within-gene range 4–6): LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4.
- chr17:51,502,488–72,237,203, 470 genes, copy number 5 (broad region; genes not listed).
- chr19:34,348,356–36,105,108, 127 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:30,278,906–64,313,132, 898 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,998. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
